Somatic mutation profile of tumor specimen TCGA-FD-A6TE-01A (aliquot TCGA-FD-A6TE-01A-12D-A339-08) from TCGA case TCGA-FD-A6TE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 54.4 years (19,874 days).
Specimen TCGA-FD-A6TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5847a41-525b-4940-802d-60046fdde2eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TE-10A (Blood Derived Normal), aliquot TCGA-FD-A6TE-10A-21D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9b56a07-de7d-486d-bddf-26409a491b22

The open-access MAF lists 259 somatic variants for this specimen: 189 protein-altering or splice-affecting, 63 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 63, Nonsense Mutation 21, RNA 3, Splice Site 3, 5'Flank 2, 3'UTR 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.167); catalogued as rs188859061, COSV66560684, COSV66576644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RB1 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | hotspot (GDC flag); catalogued as rs121913302, CM961228, CX1414765, COSV57297545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 42/45 reads (93%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 31/32 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV55862161; called by muse, mutect2
- ADGRV1 | c.4799G>A p.R1600K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV67985186; called by muse, mutect2, varscan2
- AGAP3 | c.1528A>G p.T510A (on ENST00000622464; = p.T546A on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1483645885, COSV68244623; called by mutect2, varscan2
- AKNA | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56312610; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.5557C>A p.H1853N | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.954); catalogued as COSV51847019; called by muse, mutect2, varscan2
- ANKZF1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV55476594; called by muse, mutect2, varscan2
- ANXA13 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104385388, COSV51623328; called by muse, mutect2, varscan2
- ARHGAP9 | c.1852G>A p.D618N (on ENST00000393797 / NM_001319850.2; = p.D599N on NM_032496.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.997); catalogued as COSV57361841, COSV57366220, COSV99954177; called by muse, mutect2, varscan2
- ASTN2 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs755243426, COSV57777990, COSV57788753; called by muse, mutect2, varscan2
- ATMIN | c.622C>G p.H208D | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55146078; called by muse, mutect2, varscan2
- ATP5PB | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs747473562, COSV63854017; called by muse, mutect2, varscan2
- AVPR1B | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs199633176, COSV65637644; called by muse, mutect2, varscan2
- BAIAP2L1 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV50061024, COSV99133534; called by mutect2, varscan2
- BCAS1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs373877569, COSV65085979; called by muse, mutect2, varscan2
- BSN | c.8854G>T p.E2952* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99606935; called by muse, mutect2, varscan2
- BTF3L4 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV57629760; called by muse, mutect2, varscan2
- C11orf16 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV58166439, COSV58167327; called by muse, mutect2, varscan2
- C19orf73 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV55521600; called by muse, mutect2
- CACNA2D4 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 42/62 reads (68%) | catalogued as rs568920380, COSV99764895; called by muse, mutect2, varscan2
- CAPRIN1 | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as COSV58219845; called by muse, mutect2, varscan2
- CCDC141 | c.2706G>C p.M902I | Missense Mutation (SNP) | VAF 104/122 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55373508; called by muse, mutect2, varscan2
- CDCP2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747517506, COSV61283850; called by muse, mutect2, varscan2
- CDSN | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV52538119; called by muse, mutect2, varscan2
- CEP290 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV58351767; called by mutect2, varscan2
- CEP350 | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100658228; called by muse, mutect2, varscan2
- CHI3L2 | c.1077C>G p.I359M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63874005; called by muse, mutect2, varscan2
- CHRNB2 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63807951, COSV63808176; called by muse, mutect2, varscan2
- CLK2 | c.1258G>C p.D420H (on ENST00000368361 / NM_001294339.2; = p.D419H on NM_003993.4) | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56945073; called by muse, mutect2, varscan2
- CLTCL1 | c.3307A>T p.N1103Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54230684; called by muse, mutect2, varscan2
- CNTN5 | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54310656; called by muse, mutect2, varscan2
- CNTRL | c.3590C>G p.S1197* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99440746; called by muse, mutect2, varscan2
- COL4A1 | c.3571G>A p.V1191M | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1303525775, COSV65425697; called by muse, mutect2, varscan2
- COL6A6 | c.1674C>A p.N558K | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV62025294, COSV62033809; called by muse, varscan2
- CSMD2 | c.7054G>A p.E2352K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53912443; called by muse, mutect2, varscan2
- CXXC1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV53274573; called by muse, mutect2, varscan2
- CXXC1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53274586; called by muse, mutect2, varscan2
- CYP51A1 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV50151695; called by muse, mutect2
- DAAM2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV51317997; called by muse, mutect2, varscan2
- DENND2A | c.2605C>G p.L869V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52051499; called by muse, mutect2, varscan2
- DLGAP4 | c.2116C>T p.H706Y (on ENST00000339266 / NM_001365621.1; = p.H703Y on NM_014902.6) | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV59417966; called by muse, varscan2
- DNAH5 | c.11129G>A p.R3710H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs954286214, COSV54224805; called by muse, mutect2, varscan2
- DNAI4 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV64018602; called by muse, mutect2, varscan2
- DNAJC13 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | catalogued as COSV53459748, COSV99606312; called by muse, mutect2, varscan2
- DOCK9 | c.4752G>C p.Q1584H (on ENST00000376460 / NM_001366676.2; = p.Q1585H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100237431; called by muse, mutect2, varscan2
- DONSON | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1322225569, COSV51657751; called by muse, mutect2, varscan2
- EIF2B5 | c.1276G>C p.E426Q (on ENST00000647909; = p.E418Q on NM_003907.3) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as COSV56604564; called by muse, mutect2, varscan2
- EP300 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 32/38 reads (84%) | catalogued as COSV99607021; called by muse, mutect2, varscan2
- EP400 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as COSV100200085; called by muse, mutect2, varscan2
- ERO1A | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV67471186; called by muse, mutect2, varscan2
- ESS2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.996); catalogued as rs747995432, COSV52816135; called by muse, mutect2, varscan2
- FAM189A2 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.459); catalogued as rs1209961066, COSV57384713; called by muse, mutect2, varscan2
- FAT3 | c.8245G>A p.E2749K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV53110125; called by muse, mutect2, varscan2
- FBF1 | c.1876G>A p.E626K (on ENST00000586717; = p.E640K on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1209148443, COSV100044635; called by muse, mutect2, varscan2
- FBF1 | c.1774G>C p.E592Q (on ENST00000586717; = p.E606Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as COSV59865087; called by muse, mutect2, varscan2
- FGF13 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 82/89 reads (92%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.195); catalogued as COSV59545261, COSV59545601; called by muse, mutect2, varscan2
- FGF9 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66644660; called by muse, mutect2, varscan2
- FMNL1 | c.2043C>G p.F681L | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58956942; called by muse, mutect2, varscan2
- FZD1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); catalogued as COSV55310457, COSV99842497; called by muse, mutect2, varscan2
- GABRA1 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50098702; called by muse, mutect2, varscan2
- GALNT7 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV53932817, COSV99396763; called by muse, mutect2
- GBP1 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65083443; called by muse, mutect2, varscan2
- GINM1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as COSV66389816; called by muse, mutect2, varscan2
- GLYCTK | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV59793707; called by muse, varscan2
- GNAS | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55676381; called by muse, mutect2, varscan2
- HRNR | c.5663G>A p.G1888E | Missense Mutation (SNP) | VAF 227/2208 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs765912905, COSV64254648; called by muse, mutect2, varscan2
- HSP90AA1 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs758524287, COSV53488737; called by muse, mutect2, varscan2
- IFNB1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV66525347; called by muse, mutect2, varscan2
- ITGA1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140779034; called by muse, mutect2, varscan2
- ITGA10 | c.3014C>A p.S1005Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65197404; called by muse, mutect2, varscan2
- ITGAM | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 41/55 reads (75%) | catalogued as COSV54938769, COSV54942214; called by muse, mutect2, varscan2
- ITPR2 | c.2991G>C p.K997N | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104430482, COSV67269316; called by muse, mutect2, varscan2
- JMJD1C | c.4729G>C p.E1577Q | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59514864; called by muse, mutect2, varscan2
- KAT14 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV66607702; called by muse, mutect2, varscan2
- KDM2B | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV65640809; called by muse, mutect2, varscan2
- KDM3B | c.4658G>A p.R1553K | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV58690753; called by muse, mutect2, varscan2
- KIF12 | c.1845G>C p.Q615H (on ENST00000640217; = p.Q477H on NM_138424.1) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV65117158, COSV65117335; called by muse, mutect2, varscan2
- KLHL1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.141); catalogued as COSV64772523, COSV64777755; called by muse, mutect2, varscan2
- KLRC2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV67899903; called by muse, varscan2
- KMT2D | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 57/104 reads (55%) | catalogued as COSV99976571; called by muse, mutect2, varscan2
- KRT83 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53340238; called by muse, mutect2, varscan2
- KRT84 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 81/148 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs878860575, COSV57771715; called by muse, mutect2, varscan2
- KRTAP13-3 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61879228; called by muse, mutect2, varscan2
- LRFN5 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV53256394, COSV99983125; called by muse, mutect2, varscan2
- LRP1 | c.7288G>A p.E2430K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54511253; called by muse, mutect2, varscan2
- LRRC8A | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52185773, COSV52189276; called by muse, varscan2
- LYZL1 | c.577G>A p.V193I (on ENST00000375500; = p.V147I on NM_032517.6) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs779933254, COSV64966469; called by muse, mutect2, varscan2
- MAN2B2 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53452986; called by muse, mutect2, varscan2
- MCM3AP | c.4123G>C p.E1375Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs917853669, COSV52439709; called by muse, mutect2, varscan2
- ME3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60164927; called by muse, mutect2, varscan2
- MED25 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57204434; called by muse, mutect2, varscan2
- MFSD2A | c.562G>A p.E188K (on ENST00000372809 / NM_001136493.3; = p.E175K on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.466); catalogued as rs1403232214, COSV65685215; called by muse, mutect2, varscan2
- MICAL3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99259294; called by muse, mutect2
- MYO3A | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV56323615; called by muse, mutect2, varscan2
- MYO5C | c.4948G>A p.D1650N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55899352; called by muse, mutect2, varscan2
- NECAP2 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.098); catalogued as COSV59186926; called by mutect2, varscan2
- NEK11 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100797531; called by muse, varscan2
- NEK11 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100797533; called by muse, varscan2
- NIN | c.3121G>T p.E1041* | Nonsense Mutation (SNP) | VAF 92/150 reads (61%) | catalogued as COSV99811083; called by muse, mutect2, varscan2
- NLRP1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 166/175 reads (95%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52566253; called by muse, mutect2, varscan2
- NNT | c.1108C>G p.H370D | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV52925088; called by muse, mutect2, varscan2
- NOC2L | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.225); catalogued as COSV58531804, COSV58534052; called by muse, mutect2, varscan2
- NPAP1 | c.2356C>T p.L786F | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV61505349; called by muse, mutect2, varscan2
- NR2F2 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 46/90 reads (51%) | catalogued as COSV101240897; called by muse, mutect2, varscan2
- NRXN2 | c.3217G>A p.G1073R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55453297; called by muse, mutect2, varscan2
- OR1J2 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100093048, COSV100093377; called by muse, mutect2, varscan2
- OR1L6 | c.265G>A p.D89N (on ENST00000373684; = p.D53N on NM_001004453.2) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs1447374516, COSV59028519; called by muse, mutect2, varscan2
- OR5F1 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53546449; called by muse, mutect2, varscan2
- OSBP | c.2275G>T p.E759* | Nonsense Mutation (SNP) | VAF 51/106 reads (48%) | catalogued as COSV55666141, COSV99802491; called by muse, mutect2, varscan2
- PAOX | c.771G>T p.Q257H | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as COSV53372394; called by muse, mutect2, varscan2
- PAPPA | c.2889G>C p.M963I | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV60283359, COSV60287707; called by muse, mutect2, varscan2
- PCDHB6 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1554277606, COSV50697872, COSV50704843; called by muse, mutect2, varscan2
- PHF11 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as COSV51634546; called by muse, mutect2, varscan2
- PI4KB | c.2320G>C p.E774Q (on ENST00000368873 / NM_001369623.1; = p.E786Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55017482; called by muse, mutect2, varscan2
- PIGC | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV51129903; called by muse, mutect2, varscan2
- PIK3R1 | c.635-1G>A p.X212_splice | Splice Site (SNP) | VAF 44/139 reads (32%) | catalogued as COSV57130295, COSV99074075; called by muse, mutect2, varscan2
- PIP4P2 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV53438710; called by muse, mutect2, varscan2
- PIP5K1A | c.1012G>C p.E338Q (on ENST00000368888 / NM_001135638.2; = p.E325Q on NM_003557.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV62958257; called by muse, mutect2, varscan2
- PLEKHG5 | c.2129G>C p.R710P (on ENST00000400915 / NM_001042663.3; = p.R673P on NM_020631.6) | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61068453; called by muse, mutect2
- POGLUT1 | c.1107C>A p.F369L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55156625; called by muse, varscan2
- POT1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV62930125; called by muse, mutect2, varscan2
- PPP2R2B | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.302); catalogued as COSV60764744; called by muse, mutect2, varscan2
- PRC1 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV62695308; called by muse, mutect2, varscan2
- PRR27 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV60640583; called by muse, mutect2, varscan2
- PTDSS1 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 111/197 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV61264348; called by muse, mutect2, varscan2
- PXDNL | c.2615G>A p.G872D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs771054774, COSV100687033, COSV62487345; called by muse, mutect2, varscan2
- RAB21 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99714603; called by muse, mutect2, varscan2
- RASIP1 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as COSV55804846; called by muse, mutect2, varscan2
- RBL1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV60329959; called by muse, mutect2, varscan2
- RBM8A | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.885); catalogued as rs1305682231, COSV57162226; called by muse, mutect2, varscan2
- RCOR2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs140081088; called by muse, mutect2, varscan2
- RGL2 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 50/55 reads (91%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV69916194; called by muse, mutect2, varscan2
- RNF14 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.046); catalogued as COSV61662359; called by muse, mutect2, varscan2
- RSAD2 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs143741204, COSV65908343; called by muse, mutect2, varscan2
- SCEL | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV62993500, COSV62994570; called by muse, mutect2, varscan2
- SEC14L1 | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs756976977, COSV66722276; called by muse, mutect2, varscan2
- SERPINB8 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV54639569; called by muse, mutect2, varscan2
- SLA2 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV53411213, COSV53413296; called by muse, varscan2
- SLC7A10 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as COSV53504008; called by muse, mutect2, varscan2
- SLFN5 | c.2647C>T p.H883Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55481232; called by muse, mutect2, varscan2
- SMC1A | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59129270; called by muse, mutect2, varscan2
- SOX5 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100507129, COSV58629652; called by muse, mutect2, varscan2
- SP7 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV58190891; called by muse, mutect2, varscan2
- SPNS3 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 128/145 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs566175823, COSV61070070; called by muse, mutect2, varscan2
- SPTBN4 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV58950373; called by muse, mutect2, varscan2
- SSPOP | n.6462G>C | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100022014; called by muse, mutect2, varscan2
- STAT4 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61829874; called by muse, mutect2, varscan2
- STRBP | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV62118129; called by muse, mutect2
- STRIP2 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV50804314; called by muse, mutect2, varscan2
- TAF4B | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99299421; called by muse, mutect2, varscan2
- TAF7 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 55/108 reads (51%) | catalogued as COSV100514877; called by muse, mutect2, varscan2
- TBC1D1 | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV54719000; called by muse, mutect2, varscan2
- TLR1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV58304289; called by muse, mutect2, varscan2
- TOP3A | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV58177420; called by muse, mutect2, varscan2
- TRIM41 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59319107; called by muse, mutect2, varscan2
- TRMT2A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs760056513, COSV52813470; called by muse, mutect2, varscan2
- TSPYL1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs758399636, COSV63994065; called by muse, mutect2, varscan2
- TSPYL1 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV63994068; called by muse, mutect2, varscan2
- UBE3B | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV55093736; called by muse, mutect2, varscan2
- UBR4 | c.14883C>G p.I4961M | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV64389627; called by muse, mutect2
- UCHL5 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1193317807, COSV66486398; called by muse, mutect2, varscan2
- UPRT | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV64912325; called by muse, mutect2, varscan2
- VCAM1 | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54119395; called by muse, mutect2, varscan2
- VCAM1 | c.1925G>C p.G642A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54119404; called by muse, varscan2
- VCAM1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs1393414421, COSV54118023, COSV54119414; called by muse, varscan2
- VCAM1 | c.2063G>C p.R688T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV54119421; called by muse, mutect2, varscan2
- VCP | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1554668368, CM092555, CM117903, COSV100734134, COSV62720532; called by muse, mutect2, varscan2
- VCPIP1 | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 119/214 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV60047304; called by muse, mutect2, varscan2
- VDAC2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 155/174 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV53685955; called by muse, mutect2, varscan2
- VPS13C | c.10126G>A p.D3376N (on ENST00000644861 / NM_020821.3; = p.D3333N on NM_017684.5) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); catalogued as COSV51181185; called by muse, varscan2
- WDR6 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.109); catalogued as COSV58244997; called by muse, mutect2, varscan2
- XPO1 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV68945979; called by muse, mutect2, varscan2
- YIPF1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50777256; called by muse, mutect2
- ZMIZ2 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV54808258; called by muse, mutect2, varscan2
- ZNF174 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 80/97 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV51902632, COSV51903237; called by muse, mutect2, varscan2
- ZNF263 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54596521; called by muse, mutect2, varscan2
- ZNF280A | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV57480526; called by muse, mutect2, varscan2
- ZNF330 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV53707334; called by muse, varscan2
- ZNF551 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV56592783; called by muse, mutect2, varscan2
- ZNF551 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56592798; called by muse, mutect2, varscan2
- ZNF568 | c.1814T>C p.M605T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV61741518; called by muse, mutect2, varscan2
- ZNF664 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61877756; called by muse, mutect2, varscan2
- ZNF800 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754758617, COSV56175681; called by muse, mutect2, varscan2
- ZSCAN25 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV53553055; called by muse, mutect2, varscan2
- BPGM | c.412_414del p.N138del | In Frame Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- PAPSS1 | c.593del p.P198Lfs*5 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- ACAD10 | c.1536G>C p.L512= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV58156781; called by muse, mutect2, varscan2
- ANXA13 | c.180C>T p.Y60= | Silent (SNP) | VAF 47/143 reads (33%) | catalogued as rs558516588, COSV51623341, COSV51626236; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2238C>T p.L746= (on ENST00000343619 / NM_001378531.1; = p.L740= on NM_005177.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 86/169 reads (51%) | catalogued as rs766528896, COSV52873500; called by muse, mutect2, varscan2
- ATP6V1E1 | c.9C>T p.L3= | Silent (SNP) | VAF 84/222 reads (38%) | catalogued as rs1039058721, COSV53658049; called by muse, mutect2, varscan2
- BCL2L10 | c.303G>A p.V101= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99548446; called by muse, mutect2, varscan2
- BTBD11 | c.1890G>C p.L630= (on ENST00000280758 / NM_001018072.2; = p.L167= on NM_001017523.2) | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV55024412; called by muse, mutect2, varscan2
- CDHR2 | c.1776C>T p.I592= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV56138727; called by muse, mutect2, varscan2
- CDHR2 | c.2760C>T p.D920= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs114350001, COSV56138742; called by muse, mutect2, varscan2
- CELA3B | c.300C>T p.I100= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV61404015; called by muse, mutect2, varscan2
- COL14A1 | c.1002C>T p.L334= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV52854426, COSV99921358; called by muse, mutect2, varscan2
- CX3CR1 | c.354C>T p.F118= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV100843239, COSV64193902; called by muse, mutect2, varscan2
- CYP2A13 | c.1197G>A p.L399= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as rs946422449, COSV57837764; called by muse, mutect2, varscan2
- DNAH8 | c.6084G>A p.L2028= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV59434883, COSV59445087; called by muse, mutect2, varscan2
- E2F5 | c.159G>A p.K53= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99809245; called by muse, mutect2
- EVC2 | c.2439C>T p.D813= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs370538823; called by mutect2, varscan2
- FANCD2OS | c.466C>T p.L156= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs758457130, COSV55037824; called by muse, mutect2, varscan2
- FCGBP | c.9120C>T p.I3040= | Silent (SNP) | VAF 41/213 reads (19%) | called by muse, mutect2, varscan2
- FCGBP | c.5517C>T p.I1839= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2
- FURIN | c.1956G>A p.Q652= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV51575438, COSV51576768; called by muse, mutect2, varscan2
- GUSB | c.558C>T p.I186= | Silent (SNP) | VAF 57/87 reads (66%) | catalogued as COSV59221907; called by muse, mutect2, varscan2
- HIP1R | c.2709C>G p.L903= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV53441614; called by muse, mutect2, varscan2
- INPP5E | c.1626G>A p.T542= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs150464071; ClinVar: likely benign; called by muse, mutect2, varscan2
- JAG1 | c.258C>T p.V86= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV54756872; called by muse, mutect2, varscan2
- KAT6B | c.1620G>A p.L540= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV54746820; called by muse, mutect2, varscan2
- KDM4C | c.1236C>T p.V412= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV67186497; called by muse, mutect2, varscan2
- KLHL17 | c.1377G>A p.L459= | Silent (SNP) | VAF 102/161 reads (63%) | catalogued as COSV58531814; called by muse, mutect2, varscan2
- LCN15 | c.273G>C p.L91= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV60210120; called by muse, mutect2, varscan2
- LILRB3 | c.348G>A p.V116= | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as rs755235497; called by muse, mutect2
- LRRC8A | c.1221C>T p.L407= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs951558952, COSV52184220; called by muse, mutect2, varscan2
- LRRC8A | c.1899C>A p.I633= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV52185801; called by muse, varscan2
- MAPK6 | c.46C>T p.L16= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV55929962; called by muse, mutect2, varscan2
- MKRN2 | c.660C>T p.F220= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs756518735, COSV50105148; called by muse, mutect2, varscan2
- MTRES1 | c.504C>G p.L168= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as COSV60968050; called by muse, mutect2, varscan2
- MUC17 | c.9759G>A p.L3253= | Silent (SNP) | VAF 102/215 reads (47%) | catalogued as COSV60288504; called by muse, mutect2, varscan2
- MYO18A | c.4167C>G p.L1389= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1360706671, COSV62866435; called by muse, mutect2, varscan2
- NCF2 | c.801C>A p.V267= | Silent (SNP) | VAF 52/195 reads (27%) | catalogued as COSV62315511; called by muse, mutect2, varscan2
- NYNRIN | c.4164C>T p.L1388= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs1398365727, COSV66842458; called by muse, mutect2, varscan2
- OR4C15 | c.510C>T p.A170= (on ENST00000314644; = p.A116= on NM_001001920.2) | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs1386441147, COSV58952846; called by muse, mutect2, varscan2
- PCDHB16 | c.1281G>A p.G427= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV53362276; called by muse, mutect2, varscan2
- PCDHB8 | c.1893G>A p.L631= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV50767907; called by muse, varscan2
- PCOLCE2 | c.882G>T p.V294= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV55999146, COSV55999295; called by muse, mutect2, varscan2
- PHF12 | c.618G>A p.L206= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV52019270; called by muse, mutect2, varscan2
- PLEKHA6 | c.2997G>A p.A999= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs142523085; called by muse, mutect2, varscan2
- PRAMEF18 | c.585C>T p.F195= | Silent (SNP) | VAF 58/402 reads (14%) | called by muse, mutect2, varscan2
- RASA3 | c.2076G>T p.L692= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV61867366; called by muse, mutect2, varscan2
- S1PR4 | c.504C>T p.L168= | Silent (SNP) | VAF 69/80 reads (86%) | catalogued as COSV55740256; called by muse, mutect2, varscan2
- SACS | c.12804C>T p.F4268= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV66539938; called by muse, mutect2, varscan2
- SERPINB7 | c.921C>G p.L307= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV60533897; called by muse, mutect2, varscan2
- SHC1 | c.145C>T p.L49= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV58316209; called by muse, mutect2, varscan2
- SLC7A9 | c.270C>T p.I90= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1471251540, COSV50085323; called by muse, mutect2, varscan2
- SLITRK5 | c.99C>T p.L33= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as rs755181402, COSV61522913; called by muse, mutect2, varscan2
- STAT2 | c.1044G>A p.V348= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs1050616290, COSV58475500, COSV58477513; called by muse, mutect2, varscan2
- TAOK3 | c.567G>A p.V189= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as COSV66825867; called by muse, varscan2
- TEX264 | c.582G>A p.E194= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV58134390; called by muse, mutect2, varscan2
- TMEM94 | c.324C>G p.L108= | Silent (SNP) | VAF 63/190 reads (33%) | catalogued as COSV58595631; called by muse, mutect2, varscan2
- TRIOBP | c.1647C>T p.P549= | Silent (SNP) | VAF 64/86 reads (74%) | catalogued as COSV60377459; called by muse, varscan2
- TRIOBP | c.3015C>G p.T1005= | Silent (SNP) | VAF 84/100 reads (84%) | catalogued as COSV60377466; called by muse, mutect2, varscan2
- TRPC6 | c.1221C>T p.F407= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV60252593, COSV60261480; called by muse, mutect2, varscan2
- TRRAP | c.1599G>A p.K533= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100721737; called by muse, mutect2, varscan2
- TUBGCP2 | c.1353C>T p.L451= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV53305197; called by muse, mutect2, varscan2
- UVRAG | c.678C>G p.L226= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV62104254; called by muse, mutect2, varscan2
- ZNF274 | c.1278G>A p.E426= (on ENST00000610905; = p.E321= on NM_016324.3) | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as rs766377478, COSV58764412; called by muse, mutect2, varscan2
- ZSCAN25 | c.1071C>T p.F357= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53553064; called by muse, mutect2, varscan2
- LEKR1 | c.*583G>A | 3'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as COSV62962035; called by muse, mutect2, varscan2
- MORF4 | n.964C>G | RNA (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 13/13 reads (100%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TMEM132E | chr17:34578999 G>C | 5'Flank (SNP) | VAF 55/138 reads (40%) | called by muse, mutect2, varscan2
- TXNRD3 | n.677G>T | RNA (SNP) | VAF 20/63 reads (32%) | catalogued as COSV67311788; called by muse, mutect2, varscan2
- Vault | n.49C>G | RNA (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796089 C>T | 5'Flank (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2
